Surgical pathology report (de-identified scan), TCGA case TCGA-P4-A5EA, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site  MD Anderson Cancer Center, specimen TCGA-P4-A5EA-01A (Primary Tumor).

Department of Pathology

Tissue Source Site (TSS) #:

Pathology Accession No:

Patient ID:

Normal Sample ID:

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY AND ADRENAL GLAND AND PERIAORTIC MASS:

RENAL CELL CARCINOMA,

- PAPILLARY, TYPE 2,
- FUHRMAN'S NUCLEAR GRADE 4
- 4.5 X 4.0 X 3.0 cm
- INVASION INTO THE PERIRENAL SOFT TISSUE
- LYMPHOVASCULAR INVASION PRESENT
- METASTASIS TO THE PERIRENAL SOFT TISSUE (8.0 X 6.5 X 6.0 cm).

Margins of resection (renal artery, renal vein, ureter, perinephric soft tissue), no tumor present.

Adrenal gland, no tumor present.

(B) ANTERIOR AORTA, INTER-AORTOCAVAL LYMPH NODES:

Four lymph nodes, no tumor present.

GROSS DESCRIPTION

(A) LEFT KIDNEY AND ADRENAL GLAND AND PERIAORTIC MASS - A nephroureterectomy specimen (17.0 x 12.0 x 6.5 cm) including a kidney (11.5 x 6.5 x 7.0 cm), ureter (12.0 cm length, average diameter of 0.5 cm), and adrenal gland (5.0 x 3.0 x 1.0 cm), and attached perinephric fat (9.0 x 7.5 x 2.0 cm).

There is a well-circumscribed tumor (4.5 x 4.0 x 3.0 cm) in the mid portion of the kidney. The cut surface of the kidney tumor is tan-white and homogeneous. The tumor extends to the perinephric fat and approaches the perinephric fat margin on the posterior aspect of the specimen within 0.1 cm. The tumor does not appear to extend into the sinus. There is a perihilar lymph node (8.0 x 6.5 x 6.0 cm) in the attached perinephric fat. Serial sectioning of the hilar lymph node shows a tan-white, firm and homogeneous cut surface with focal area of hemorrhage and necrosis.

The uninvolved kidney is tan-brown and grossly unremarkable. The adrenal gland is grossly unremarkable. The remainder of the urothelium of the pelvicalyceal system is grossly unremarkable.

Representative sections are submitted in A1-A21. Representative sample of the tumor is submitted for electron microscopy (on hold).

INK CODE: Blue - retroperitoneal fat margin.

SECTION CODE: A1, vascular and ureter margin; A2, adrenal gland; A3, tumor and perirenal soft tissue; A4-A6, tumor and renal sinus; A7-A12, tumor; A13-A18, representative sections of the perihilar lymph node; A19, A20, uninvolved kidney; A21, renal pelvis.

(B) ANTERIOR AORTA INTER-AORTOCAVAL LYMPH NODES - An irregular fragment of adipose tissue (5.0 x 2.0 x 1.0 cm).

Four lymph nodes are identified ranging from 0.4 x 0.4 x 0.2 to 1.0 x 0.8 x 0.4 cm.

SECTION CODE: B1, B2, one lymph node serially sectioned; B3, three lymph nodes.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-Y7343

"Some tests reported here may have been developed and performance characteristics determined by

These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

—END OF REPORT—

ICD O-3
Carcinoma, papillary renal cell
82601.3
Site: @ Kidney NOS C64.9
JAD 1/10/13

Source: NCI Genomic Data Commons file f0f0bcfe-f9ad-4884-ac35-7616bad552d6 (TCGA-P4-A5EA.BF121A0C-1D1B-4F4F-BBA3-C90325BA4FD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).